Somatic mutation profile of tumor specimen TCGA-ER-A42K-06A (aliquot TCGA-ER-A42K-06A-11D-A24R-08) from TCGA case TCGA-ER-A42K, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.1 years (14,663 days).
Specimen TCGA-ER-A42K-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6240411c-11b4-4f95-85ed-db4ed39482d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A42K-10A (Blood Derived Normal), aliquot TCGA-ER-A42K-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed88ce5-56c9-4a42-8f62-3ac6de8f88f2

The open-access MAF lists 249 somatic variants for this specimen: 163 protein-altering or splice-affecting, 78 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 78, Nonsense Mutation 13, Splice Site 4, Intron 3, RNA 2, Frame Shift Del 2, 5'Flank 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/144 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.2069C>T p.P690L (on ENST00000404938 / NM_001163941.2; = p.P245L on NM_178559.6) | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV51722443; called by muse, mutect2, varscan2
- ABL2 | c.2465C>T p.P822L (on ENST00000502732 / NM_007314.4; = p.P807L on NM_005158.5) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV61021366; called by muse, mutect2, varscan2
- ABRA | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733802; called by muse, mutect2, varscan2
- ACO1 | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as COSV59385523; called by muse, mutect2, varscan2
- ADRM1 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV99440230; called by muse, mutect2, varscan2
- ALDH3A1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV56737183; called by muse, mutect2
- AMPD2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56651266; called by muse, mutect2, varscan2
- AMY2A | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101340641; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5570C>T p.A1857V | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs750445906, COSV51860059; called by muse, mutect2, varscan2
- AREG | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99144392; called by muse, mutect2, varscan2
- ASTN2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as rs775976088, COSV57778302; called by muse, mutect2, varscan2
- ATP8A1 | c.708G>T p.R236S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.139); catalogued as rs1441543384, COSV52549871; called by muse, mutect2, varscan2
- C16orf70 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54629688; called by muse, mutect2, varscan2
- CALCRL | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs780410767, COSV66476839, COSV66477899; called by muse, mutect2, varscan2
- CAMKK2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201263450, COSV100242986; called by muse, varscan2
- CAV3 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs867303882, COSV100664404, COSV59562583; called by muse, mutect2, varscan2
- CCDC184 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV57252607; called by muse, mutect2, varscan2
- CCDC80 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV52820378; called by muse, mutect2, varscan2
- CCER1 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); catalogued as COSV62648903; called by muse, mutect2, varscan2
- CD1E | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as rs775938225, COSV63770003, COSV63770928; called by muse, mutect2, varscan2
- CDH7 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.402); catalogued as COSV59888680; called by muse, varscan2
- CEP152 | c.4876A>G p.I1626V (on ENST00000380950 / NM_001194998.2; = p.I1570V on NM_014985.4) | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV57865579; called by muse, mutect2, varscan2
- CFAP43 | c.2483A>T p.N828I | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53381932; called by muse, mutect2, varscan2
- CFAP45 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV63651363; called by muse, mutect2, varscan2
- CGGBP1 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58853241; called by muse, mutect2, varscan2
- CNNM4 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65662269; called by muse, mutect2, varscan2
- CNTROB | c.2272C>T p.H758Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.909); catalogued as COSV66609622; called by muse, mutect2, varscan2
- COL11A1 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs757495447, COSV62200202; called by muse, mutect2, varscan2
- COL26A1 | c.925C>T p.P309S (on ENST00000313669 / NM_001278563.3; = p.P307S on NM_133457.4) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.373); catalogued as rs754486613, COSV58129334; called by muse, varscan2
- COL26A1 | c.926C>T p.P309L (on ENST00000313669 / NM_001278563.3; = p.P307L on NM_133457.4) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.562); catalogued as COSV100561783; called by muse, mutect2, varscan2
- COL4A4 | c.3974-1G>A p.X1325_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61637252; called by muse, mutect2, varscan2
- COL5A2 | c.3926G>A p.G1309D | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs863223497, COSV66416095; ClinVar: uncertain significance; called by muse, mutect2
- CRB2 | c.3811G>A p.E1271K | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63505912; called by muse, mutect2, varscan2
- CYP19A1 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV53058702; called by muse, mutect2, varscan2
- DNMT3B | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs1226308460, COSV52416376; called by muse, mutect2, varscan2
- DSC3 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV64575824; called by muse, mutect2, varscan2
- EMID1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs747098153, COSV61830983; called by muse, mutect2, varscan2
- ERBB2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54084502; called by muse, mutect2, varscan2
- FAM155A | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV65590366; called by muse, mutect2, varscan2
- FAM83B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60919935; called by muse, mutect2, varscan2
- FBXL7 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100309866; called by muse, mutect2, varscan2
- FHOD1 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50772164; called by muse, mutect2, varscan2
- FLG | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 179/673 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs745887774, COSV64251104; called by muse, mutect2, varscan2
- FLG | c.3217G>A p.D1073N | Missense Mutation (SNP) | VAF 267/1089 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV64251113; called by muse, mutect2, varscan2
- FOLR3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs370372415; called by muse, mutect2, varscan2
- FSHR | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.982); catalogued as COSV58636592; called by muse, mutect2, varscan2
- GFOD1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as rs868282677, COSV64955484; called by muse, mutect2, varscan2
- GLI3 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs779595377, COSV67895617; called by muse, mutect2, varscan2
- GRID2 | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV56276790; called by muse, mutect2, varscan2
- GRIP1 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54045609; called by muse, mutect2, varscan2
- GRM4 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV65220545; called by muse, mutect2, varscan2
- GSDMC | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52696915, COSV52699920; called by muse, mutect2, varscan2
- HGSNAT | c.1791G>C p.W597C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52819515; called by muse, mutect2, varscan2
- HINFP | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63432830; called by muse, mutect2, varscan2
- IFT74 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66289051; called by muse, mutect2, varscan2
- INPP5K | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs759025302, COSV57443110; called by muse, mutect2, varscan2
- ITGA4 | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV59214598; called by muse, mutect2, varscan2
- ITM2C | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs768954876, COSV58400437; called by muse, mutect2
- JAKMIP1 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV51546940; called by muse, mutect2, varscan2
- KCNQ5 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1486380739, COSV59685510; called by muse, mutect2, varscan2
- KCNT2 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs773845489, COSV54068516; called by muse, mutect2, varscan2
- KCNV1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV52089511; called by muse, mutect2, varscan2
- KDM3B | c.4636T>C p.L1546= | Splice Region (SNP) | VAF 118/267 reads (44%) | catalogued as COSV58696041; called by muse, mutect2, varscan2
- KLK6 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59566880; called by muse, mutect2, varscan2
- KRT2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59013011; called by muse, mutect2, varscan2
- KRT39 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV62918138; called by muse, mutect2, varscan2
- KRT5 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52863848; called by muse, mutect2, varscan2
- KRTAP10-5 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs587720012, COSV59982311; called by muse, mutect2, varscan2
- KRTAP10-8 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58167428; called by muse, mutect2, varscan2
- L3MBTL4 | c.1374A>T p.R458S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53143070; called by muse, mutect2, varscan2
- LAMP1 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58152504; called by muse, mutect2, varscan2
- LCOR | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs150999644, COSV53718678; called by muse, mutect2, varscan2
- LGI3 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1439213289, COSV100103093; called by muse, mutect2, varscan2
- LIMCH1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs762979334, COSV58292164, COSV58298880; called by muse, mutect2, varscan2
- LOXL3 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs750770185, COSV51215887; called by muse, mutect2, varscan2
- LPA | c.5430A>C p.Q1810H | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as COSV60300733, COSV60312925; called by muse, mutect2, varscan2
- LRP1B | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV67280802; called by muse, mutect2, varscan2
- MAGEA12 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 138/190 reads (73%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV100756937; called by muse, mutect2, varscan2
- MAP2 | c.3473C>T p.S1158L | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as COSV52310545; called by muse, mutect2, varscan2
- MAPKAPK2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs782231165, COSV54318989, COSV99686238; called by muse, mutect2, varscan2
- MAPKBP1 | c.918C>G p.N306K (on ENST00000456763 / NM_001128608.2; = p.N300K on NM_014994.3) | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV52967652; called by muse, mutect2, varscan2
- MCF2L | c.3029C>T p.P1010L (on ENST00000375608; = p.P978L on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56182499; called by muse, mutect2, varscan2
- METTL22 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV50838952; called by muse, mutect2
- MSH3 | c.1027+2T>A p.X343_splice | Splice Site (SNP) | VAF 37/115 reads (32%) | catalogued as COSV54166319; called by muse, mutect2, varscan2
- MYH15 | c.5319+1G>A p.X1773_splice | Splice Site (SNP) | VAF 55/123 reads (45%) | catalogued as COSV56321297; called by muse, mutect2, varscan2
- MYH2 | c.5222C>T p.S1741F | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV55442525; called by muse, mutect2, varscan2
- MYO1F | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV57800427; called by muse, mutect2, varscan2
- MYRIP | c.1665+2T>C p.X555_splice | Splice Site (SNP) | VAF 22/47 reads (47%) | catalogued as COSV56883954; called by muse, mutect2, varscan2
- NCOA6 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV62868538; called by muse, mutect2, varscan2
- NFASC | c.3104C>G p.P1035R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.571); catalogued as COSV100363940; called by muse, mutect2, varscan2
- NME8 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV52256073; called by muse, mutect2, varscan2
- NOP14 | c.2050C>G p.R684G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58628273; called by muse, mutect2, varscan2
- NUAK1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs753190492, COSV54609014; called by muse, mutect2, varscan2
- OAZ3 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1392624689, COSV58618710, COSV58619972, COSV58620751; called by muse, mutect2, varscan2
- OR52K2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 134/181 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs556746206, COSV57835317; called by muse, mutect2, varscan2
- PACSIN1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs751104600, COSV55062760; called by muse, mutect2, varscan2
- PCED1B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71394934; called by muse, mutect2, varscan2
- PCLO | c.12875C>T p.S4292F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61672760; called by muse, mutect2, varscan2
- PDE8B | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1215539475, COSV53746864; called by muse, mutect2, varscan2
- PIBF1 | c.2087A>T p.H696L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV58328954; called by muse, mutect2, varscan2
- PKDREJ | c.6343G>A p.E2115K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53553051, COSV99478905; called by muse, mutect2, varscan2
- PLCZ1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.631); catalogued as COSV56859537, COSV99856951; called by muse, mutect2, varscan2
- PRAMEF4 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV52441821; called by muse, mutect2, varscan2
- PROS1 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67777564; called by muse, mutect2, varscan2
- PSG2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV68884558, COSV68885076; called by muse, mutect2, varscan2
- PSMD6 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55761582; called by muse, mutect2, varscan2
- PTEN | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1554893808, CM110124, COSV64297332, COSV64308587, COSV64311451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRN | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55352828, COSV99834166; called by muse, mutect2, varscan2
- PXDNL | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs756848491, COSV62500182; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.061); catalogued as COSV54764648; called by muse, mutect2, varscan2
- RASSF9 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs569219332, COSV63435284; called by muse, mutect2, varscan2
- RC3H2 | c.2356C>T p.H786Y | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100605621, COSV61802814; called by muse, mutect2, varscan2
- REP15 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57293261, COSV57299625; called by muse, mutect2, varscan2
- RNF185 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs766520075, COSV56737184; called by muse, mutect2, varscan2
- RNF43 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1262556898, COSV68460029; called by muse, mutect2, varscan2
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RP1 | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs267601954, COSV55128472; called by muse, mutect2, varscan2
- RPRD1A | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59823556; called by muse, mutect2, varscan2
- SBSPON | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.851); catalogued as COSV52078361; called by muse, mutect2, varscan2
- SCN2A | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1085307603, COSV51857442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA4 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV54071344; called by muse, mutect2, varscan2
- SH3PXD2B | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61130842; called by muse, mutect2, varscan2
- SLC1A7 | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65201604; called by muse, mutect2
- SLC25A40 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 89/164 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs775550958, COSV62021938; called by muse, mutect2, varscan2
- SLC27A6 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as COSV99322739; called by muse, mutect2, varscan2
- SLC5A11 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100762752, COSV61743884; called by muse, mutect2, varscan2
- SLC5A9 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.17); catalogued as rs764095817, COSV99361683; called by muse, mutect2, varscan2
- SLC7A3 | c.1643C>A p.P548Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53229633; called by muse, mutect2
- SLCO1B3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746941097, COSV53933044; called by muse, mutect2, varscan2
- SLFN11 | c.362T>A p.V121D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV57700863; called by muse, mutect2, varscan2
- SLITRK1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV65677893; called by muse, mutect2, varscan2
- SLITRK1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1274976383, COSV65677898; called by muse, mutect2, varscan2
- SMARCB1 | c.964C>T p.Q322* (on ENST00000263121; = p.Q368* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 32/107 reads (30%) | catalogued as COSV51954323; called by muse, mutect2, varscan2
- SNX24 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV54456849; called by muse, mutect2, varscan2
- SPTA1 | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV63752174; called by muse, mutect2, varscan2
- STXBP5L | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56507809; called by muse, mutect2, varscan2
- SULT1C3 | c.701A>T p.Y234F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV61254784; called by muse, mutect2, varscan2
- SUPT7L | c.1209C>A p.F403L | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV53118010; called by muse, mutect2, varscan2
- TARS3 | c.1720C>T p.Q574* | Nonsense Mutation (SNP) | VAF 71/137 reads (52%) | catalogued as COSV60109867; called by muse, mutect2, varscan2
- TEX44 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58355640; called by muse, mutect2, varscan2
- TFEC | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 124/225 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV55407942; called by muse, mutect2, varscan2
- TIGD4 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs757414100, COSV58548890; called by muse, mutect2, varscan2
- TLR8 | c.2906A>T p.D969V (on ENST00000218032 / NM_138636.5; = p.D987V on NM_016610.4) | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54321307; called by muse, mutect2, varscan2
- TMC2 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs757554442, COSV62653247; called by muse, mutect2, varscan2
- TMCC3 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54158232; called by muse, mutect2, varscan2
- TMEM132B | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as COSV100170480, COSV54772824; called by muse, mutect2, varscan2
- TNIK | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.152); catalogued as COSV52698255; called by muse, mutect2, varscan2
- TNXB | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64490167; called by muse, mutect2
- TNXB | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100926363; called by muse, mutect2
- TRIM2 | c.1196G>A p.G399E (on ENST00000437508; = p.G426E on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58639433; called by muse, mutect2, varscan2
- TRIM58 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 122/189 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63572514; called by muse, mutect2, varscan2
- TSGA10IP | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV73245448; called by muse, mutect2, varscan2
- TTI1 | c.1007T>A p.L336* | Nonsense Mutation (SNP) | VAF 72/214 reads (34%) | catalogued as COSV65064033; called by muse, mutect2, varscan2
- WDR3 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV62525619; called by muse, mutect2, varscan2
- WWP2 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138762665; called by muse, varscan2
- ZMYM1 | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as COSV63250617; called by muse, mutect2, varscan2
- ZNF135 | c.365G>A p.W122* (on ENST00000313434 / NM_001289401.2; = p.W134* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV57886516; called by muse, mutect2, varscan2
- ZNF93 | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV59375766; called by muse, mutect2, varscan2
- CCDC144A | c.4249C>A p.Q1417K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CCL23 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51A2 | c.685del p.I229Lfs*21 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel
- OR51A4 | c.685del p.I229Lfs*21 | Frame Shift Del (DEL) | VAF 38/66 reads (58%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2781C>T p.A927= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV65901203; called by muse, mutect2, varscan2
- ADRM1 | c.918C>T p.V306= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV99440229; called by muse, mutect2, varscan2
- APBB1IP | c.1218C>T p.T406= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as COSV66136864; called by muse, mutect2, varscan2
- APOL3 | c.447G>A p.R149= (on ENST00000349314 / NM_145640.2; = p.R78= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV62579194; called by muse, mutect2, varscan2
- ARHGAP25 | c.579G>A p.R193= (on ENST00000409202 / NM_001007231.3; = p.R185= on NM_014882.3) | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV54910063; called by muse, mutect2, varscan2
- AXL | c.1521G>A p.R507= (on ENST00000301178 / NM_021913.5; = p.R498= on NM_001699.6) | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as COSV56575874; called by muse, mutect2, varscan2
- CAMKK2 | c.423C>T p.P141= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100242989; called by muse, mutect2, varscan2
- CD274 | c.822C>T p.I274= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV67501126; called by muse, mutect2, varscan2
- CD2BP2 | c.492C>T p.L164= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs753513851, COSV59770026; called by muse, mutect2, varscan2
- COLGALT1 | c.1329C>T p.F443= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs1205257142, COSV53111802; called by muse, mutect2, varscan2
- DNAH7 | c.11553G>A p.V3851= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV56756398; called by muse, mutect2, varscan2
- DSC2 | c.2131C>T p.L711= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs1214149293, COSV51870136; called by muse, mutect2, varscan2
- EDA | c.972G>A p.V324= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV65785835; called by muse, mutect2, varscan2
- EPN3 | c.498G>A p.L166= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99276996; called by muse, mutect2, varscan2
- FAM71D | c.195C>T p.N65= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV61296820; called by muse, mutect2, varscan2
- FBXL7 | c.1029G>A p.R343= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100309864; called by muse, mutect2, varscan2
- FGF14 | c.645G>A p.G215= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs960596448, COSV65959857; called by muse, mutect2, varscan2
- FGR | c.1024T>C p.L342= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV64969873; called by muse, mutect2
- FSHR | c.1914C>T p.F638= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV58636577; called by muse, mutect2, varscan2
- GABRB2 | c.1512C>T p.I504= (on ENST00000274547; = p.I466= on NM_000813.3) | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs761305470, COSV50903532; called by muse, mutect2, varscan2
- GALNT6 | c.1866C>T p.V622= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs750873631, COSV62543533; called by muse, mutect2
- GALNT9 | c.1662C>T p.T554= (on ENST00000328957 / NM_001122636.2; = p.T188= on NM_021808.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1274880760; called by muse, mutect2
- GPATCH8 | c.3927C>T p.P1309= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV59199105; called by muse, mutect2, varscan2
- GPC5 | c.234G>A p.Q78= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV65632653; called by muse, mutect2, varscan2
- GSDMA | c.90C>T p.F30= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV56980239; called by muse, mutect2, varscan2
- GSDMA | c.1005C>T p.F335= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs745919621, COSV100053677, COSV56975339; called by muse, mutect2, varscan2
- HRNR | c.6066A>T p.A2022= | Silent (SNP) | VAF 426/2189 reads (19%) | catalogued as COSV64263509; called by muse, mutect2, varscan2
- HYDIN | c.6627C>T p.L2209= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs760277100, COSV59272843; called by muse, mutect2, varscan2
- IGSF1 | c.2508C>T p.I836= | Silent (SNP) | VAF 227/328 reads (69%) | catalogued as COSV63838365, COSV63840222; called by muse, mutect2, varscan2
- IQCE | c.1824C>T p.I608= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV58082456; called by muse, mutect2, varscan2
- IQGAP1 | c.3816C>T p.V1272= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV51592079; called by muse, mutect2, varscan2
- ISOC2 | c.354G>A p.T118= (on ENST00000425675 / NM_001136201.2; = p.T134= on NM_024710.3) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs767043339, COSV50035474; called by muse, mutect2, varscan2
- KIF20B | c.3159C>T p.F1053= (on ENST00000371728 / NM_001284259.2; = p.F1013= on NM_016195.4) | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as COSV53316515; called by muse, mutect2, varscan2
- LGI3 | c.138C>T p.T46= | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as COSV100103092; called by muse, mutect2, varscan2
- LRRIQ4 | c.813G>A p.K271= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV61620416; called by muse, mutect2, varscan2
- MAGEA12 | c.648C>T p.A216= | Silent (SNP) | VAF 137/192 reads (71%) | catalogued as COSV100756938; called by muse, mutect2, varscan2
- MECR | c.111C>T p.S37= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV55287962; called by muse, mutect2, varscan2
- MYEOV | c.430C>T p.L144= | Silent (SNP) | VAF 96/310 reads (31%) | catalogued as rs1415721392, COSV58295157, COSV58295433; called by muse, mutect2, varscan2
- MYH2 | c.1746G>A p.L582= | Silent (SNP) | VAF 85/208 reads (41%) | catalogued as rs778765592, COSV55450186; called by muse, mutect2, varscan2
- MYO3A | c.1302T>G p.G434= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV56351963; called by muse, mutect2, varscan2
- NPNT | c.1170A>G p.Q390= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV59757432; called by muse, mutect2, varscan2
- NRP1 | c.756G>A p.A252= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as rs1375059208, COSV55164984; called by muse, mutect2, varscan2
- NRP2 | c.2790G>A p.E930= (on ENST00000360409 / NM_201266.2; = p.E925= on NM_003872.3) | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV63378787; called by muse, mutect2, varscan2
- OR4A5 | c.420C>T p.F140= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as rs1282376873, COSV60522576; called by muse, mutect2, varscan2
- OR51A7 | c.663G>A p.L221= | Silent (SNP) | VAF 93/119 reads (78%) | catalogued as COSV63789077; called by muse, mutect2, varscan2
- OR8J1 | c.630C>T p.S210= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV57320361; called by muse, mutect2, varscan2
- PCDHA2 | c.48C>T p.L16= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs782681638, COSV65371650; called by muse, mutect2, varscan2
- PCDHGA2 | c.1710C>T p.D570= | Silent (SNP) | VAF 123/268 reads (46%) | catalogued as rs770524150, COSV53935080; called by muse, mutect2, varscan2
- PGLYRP2 | c.291G>A p.V97= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV52998506; called by muse, mutect2, varscan2
- PLA2G4E | c.1557G>A p.K519= | Silent (SNP) | VAF 124/294 reads (42%) | catalogued as rs751281433, COSV68152729; called by muse, mutect2, varscan2
- PLB1 | c.1098G>A p.A366= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs773909974, COSV59829401; called by muse, mutect2, varscan2
- PLEKHG5 | c.610C>T p.L204= (on ENST00000400915 / NM_001042663.3; = p.L167= on NM_020631.6) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV61706473; called by muse, mutect2, varscan2
- PTTG2 | c.12G>A p.L4= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54728348; called by muse, mutect2, varscan2
- RAB5B | c.565C>T p.L189= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs923837637, COSV64365355; called by muse, mutect2, varscan2
- RAD51D | c.555C>T p.L185= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60006347; called by muse, mutect2, varscan2
- RBPMS2 | c.405C>T p.I135= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs370260267; called by muse, mutect2, varscan2
- SCN9A | c.282G>A p.G94= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV57611264; called by muse, mutect2, varscan2
- SHCBP1L | c.585A>C p.S195= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV62357555; called by muse, mutect2, varscan2
- SLC25A27 | c.198C>T p.A66= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as COSV51498496, COSV51499774; called by muse, mutect2, varscan2
- SLC26A11 | c.57C>T p.A19= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV58340804; called by muse, mutect2, varscan2
- SLC27A6 | c.495G>A p.T165= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs148544932, COSV99322738, COSV99323566; called by muse, mutect2, varscan2
- SLC2A9 | c.1182C>T p.F394= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53322166; called by muse, mutect2, varscan2
- SPATA20 | c.420C>T p.D140= (on ENST00000356488 / NM_001258372.1; = p.D156= on NM_022827.4) | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV50070909; called by muse, mutect2, varscan2
- SRRM4 | c.1503G>A p.P501= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV57429364; called by muse, mutect2, varscan2
- ST8SIA2 | c.522G>A p.E174= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1402779863, COSV51573548; called by muse, mutect2, varscan2
- STRC | c.4764C>T p.F1588= | Silent (SNP) | VAF 73/185 reads (39%) | catalogued as rs772901207, COSV55853497; called by muse, mutect2, varscan2
- SULT2B1 | c.525C>T p.F175= (on ENST00000201586 / NM_177973.2; = p.F160= on NM_004605.2) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52379142; called by muse, mutect2, varscan2
- SYNE2 | c.14733T>C p.C4911= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV59972766; called by muse, mutect2, varscan2
- TACC3 | c.208C>T p.L70= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs761960985, COSV57560289; called by muse, mutect2, varscan2
- TBC1D1 | c.579C>T p.I193= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as COSV54721941; called by muse, mutect2, varscan2
- TBCCD1 | c.642C>T p.F214= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as COSV58663787; called by muse, mutect2, varscan2
- TRIM58 | c.906G>A p.P302= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs769728891, COSV63570969; called by muse, mutect2, varscan2
- UGT2B28 | c.402G>A p.K134= | Silent (SNP) | VAF 66/79 reads (84%) | catalogued as COSV59431046, COSV59434787; called by muse, mutect2, varscan2
- UNC5B | c.1890C>T p.A630= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as COSV58981905; called by muse, mutect2, varscan2
- WDR19 | c.3726T>C p.D1242= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV56470708; called by muse, mutect2
- XCR1 | c.765C>T p.I255= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1224788608, COSV58569818, COSV58570952; called by muse, mutect2, varscan2
- ZNF135 | c.1752G>A p.G584= (on ENST00000313434 / NM_001289401.2; = p.G596= on NM_003436.4) | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV57886542; called by muse, mutect2, varscan2
- ZNF169 | c.285T>C p.F95= | Silent (SNP) | VAF 69/85 reads (81%) | catalogued as COSV61766908; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208425 C>T | 5'Flank (SNP) | VAF 183/402 reads (46%) | called by muse, mutect2, varscan2
- ARFRP1 | c.417+462C>T | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs557132820, COSV99422730; called by muse, varscan2
- MBNL1 | c.174+40532C>T | Intron (SNP) | VAF 19/61 reads (31%) | catalogued as COSV56836547; called by muse, mutect2, varscan2
- MECR | c.756+498C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397798 G>A | 3'Flank (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- MORF4 | n.881C>T | RNA (SNP) | VAF 46/115 reads (40%) | catalogued as rs1327713036; called by muse, mutect2, varscan2
- SPACA6 | chr19:51692841 T>C | 5'Flank (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- SSPOP | n.2907G>A | RNA (SNP) | VAF 68/112 reads (61%) | catalogued as rs371253865; called by muse, mutect2, varscan2
